Surgical pathology report (de-identified scan), TCGA case TCGA-P5-A72W, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Cureline, specimen TCGA-P5-A72W-01A (Primary Tumor).

ICD O-3
Astrocytoma, grade III 9401/3
Site: Brain, supratentorial NOS
C71.2
JW 8/15/13

Case #

Patient: Age (years): Gender:

Clinical diagnosis: Brain tumor

Date of procurement:

Sample:

Gross description:

Material presented, from left frontal lobe, by brain tissue with extended gray and white matter, soft, with a brownish blurred structure

Microscopic description:

Diffuse astrocytoma, Ki 67 proliferative activity less than 10%, grade II-III.

Final diagnosis: Diffuse astrocytoma Grade III

Confidential

Source: NCI Genomic Data Commons file f14d7b27-5179-4573-b9dd-016112585330 (TCGA-P5-A72W.5BBDAFDC-37F6-4750-9F67-EF32F7B023FA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).